Somatic mutation profile of tumor specimen MP2PRT-PATDUT-TMP1-A (aliquot MP2PRT-PATDUT-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATDUT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,154 days).
Specimen MP2PRT-PATDUT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ab50a1e-c109-430e-8498-b2e9a00dc96a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATDUT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATDUT-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f08fb24b-c7da-487a-9c33-873887ae5353

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, 3'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/398 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 36/513 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 104/302 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CGNL1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs770201755; called by muse, mutect2, varscan2
- FAT3 | c.12887G>A p.R4296H | Missense Mutation (SNP) | VAF 108/366 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.964); catalogued as rs770812535, COSV99968810; called by muse, varscan2
- IGF2R | c.5675G>A p.R1892H | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.297); catalogued as rs149633151; called by muse, mutect2, varscan2
- MDGA1 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 22/460 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs778497435; called by muse, mutect2
- PPP1R13B | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 86/429 reads (20%) | catalogued as COSV52448739; called by muse, mutect2, varscan2
- TRAV34 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747936082; called by muse, mutect2
- ZCCHC14 | c.456C>G p.N152K (on ENST00000268616; = p.N289K on NM_015144.3) | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs1212822038; called by muse, mutect2, varscan2
- BAZ1A | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.278); called by muse, mutect2
- GABRA1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); called by muse, varscan2
- IGHV4-59 | c.344_345insCT p.R116* | Frame Shift Ins (INS) | VAF 37/267 reads (14%) | called by mutect2, pindel, varscan2
- UBA5 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF69 | c.196A>T p.S66C (on ENST00000429654 / NM_001364730.1; = p.S52C on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2
- COL4A6 | c.1281C>A p.G427= | Silent (SNP) | VAF 44/924 reads (5%) | catalogued as rs748786874; called by muse, mutect2
- PPP1R12A | c.438G>A p.A146= | Silent (SNP) | VAF 29/310 reads (9%) | catalogued as rs554396604, COSV99700130; called by muse, mutect2
- SPTBN2 | c.3036C>T p.A1012= | Silent (SNP) | VAF 42/604 reads (7%) | catalogued as rs750622290; called by muse, mutect2
- TRDV2 | chr14:22423042 ins CCCCGAGATGTCGCTTT | 3'Flank (INS) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
